Somatic mutation profile of tumor specimen TCGA-AB-2829-03B (aliquot TCGA-AB-2829-03B-01W-0728-08) from TCGA case TCGA-AB-2829, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, M6 type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.3 years (18,386 days).
Specimen TCGA-AB-2829-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5337c44c-b186-4f5c-be0e-ba8fef50fb99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2829-11B (Solid Tissue Normal), aliquot TCGA-AB-2829-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/577a19b9-6ee7-4be0-9e68-84421425f79d

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Splice Site 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 59/158 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 130/404 reads (32%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs376179210; called by muse, varscan2
- CNOT6 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs143354534, COSV56161669; called by muse, mutect2, varscan2
- EIF5B | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99177012; called by muse, mutect2
- EIF5B | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV99177016; called by muse, mutect2
- HSPA13 | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772949719, COSV53464428; called by muse, mutect2
- ITPR1 | c.6533G>A p.G2178D (on ENST00000354582; = p.G2123D on NM_002222.7) | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.283); catalogued as COSV56966137; called by muse, mutect2, varscan2
- PIWIL4 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54406842; called by muse, mutect2, varscan2
- RNF152 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs377278409; called by muse, mutect2, varscan2
- RPL4 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs1567034808, COSV57177886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC43A1 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs377101978, COSV53557091; called by muse, mutect2, varscan2
- MZF1 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- RSF1 | c.3326_3341+4del p.X1109_splice | Splice Site (DEL) | VAF 33/182 reads (18%) | called by mutect2, pindel, varscan2
- NTRK3 | c.1266C>T p.T422= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV100446327, COSV58106859; called by muse, mutect2, varscan2
